Somatic mutation profile of tumor specimen MP2PRT-PATZFJ-TMP1-A (aliquot MP2PRT-PATZFJ-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PATZFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,658 days).
Specimen MP2PRT-PATZFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64168d72-6c82-4500-b8ba-0263562a5046.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZFJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZFJ-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbc3648a-b941-4a58-958b-a3d6994ae0c3

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Frame Shift Ins 2, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 30/467 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADAMTSL4 | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 186/459 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752027574; called by muse, mutect2, varscan2
- CARD10 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 172/398 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52657302; called by muse, mutect2, varscan2
- PLCH2 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 77/349 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752247217, COSV53948622; called by muse, mutect2, varscan2
- BBX | c.2789_2790insAGGG p.Q931Gfs*11 (on ENST00000325805 / NM_001142568.3; = p.Q901Gfs*11 on NM_020235.7) | Frame Shift Ins (INS) | VAF 69/453 reads (15%) | called by mutect2, varscan2*
- BBX | c.2791_2792insCCGTAGG p.Q931Pfs*12 (on ENST00000325805 / NM_001142568.3; = p.Q901Pfs*12 on NM_020235.7) | Frame Shift Ins (INS) | VAF 69/461 reads (15%) | called by mutect2, pindel*, varscan2*
- GJA8 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- IGHV3-30 | chr14:106335078 TGTCTTTC>CCTAGGG | Missense Mutation (DEL) | VAF 106/211 reads (50%) | called by pindel, varscan2*
- NPSR1 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 143/333 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SBF2 | c.4932+1G>C p.X1644_splice | Splice Site (SNP) | VAF 28/223 reads (13%) | called by muse, mutect2, varscan2
- SMUG1 | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 188/470 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO2 | c.177G>A p.T59= | Silent (SNP) | VAF 189/440 reads (43%) | catalogued as rs762225187, COSV59907559; called by muse, mutect2, varscan2
